Gene-level copy-number profile of tumor specimen ALCH-B211-TTP1-A from ALCHEMIST case ALCH-B211, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.5 years (25,755 days).
Specimen ALCH-B211-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 934e623c-5d0b-401a-85c4-3fcd81b5ec0f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B211-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/38e015db-526e-45cf-914a-ec91f4bd831d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 516; copy number 1: 11,785; copy number 2: 43,916; copy number 3: 1,958; copy number 4: 292; copy number 5: 41; copy number 6: 16; copy number 7: 52; copy number 8: 161; copy number 9: 95; copy number 11: 75; copy number 13: 7.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:54,132,686–54,200,073, 3 genes (within-gene range 0–1): AL357673.1, CDCP2, AL357673.2.
- chr22:41,525,799–41,544,606, 1 gene (within-gene range 0–2): POLR3H.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 447 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:177,111,036–177,212,662, 1 gene, copy number 6 (within-gene range 2–6): AC079305.2.
- chr2:177,194,983–177,392,697, 15 genes, copy number 6 (within-gene range 2–6): Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2.
- chr2:210,171,518–210,679,107, 8 genes, copy number 5: AC006994.1, ACADL, Y_RNA, MYL1, LANCL1-AS1, LANCL1, CPS1, CPS1-IT1.
- chr3:167,864,773–183,116,075, 236 genes, copy number 8–11 (broad region; genes not listed).
- chr10:38,762,095–38,783,108, 2 genes, copy number 5: AL133173.1, AL590623.1.
- chr11:68,870,664–73,369,388, 154 genes, copy number 7–13 (broad region; genes not listed).
- chr11:77,216,558–78,215,232, 31 genes, copy number 5: GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35.

Autosomal genes at a single copy (total copy number 1): 9,798. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
